FM case AD6920 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mucoepidermoid Neoplasms; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/36fc6e5c-2c13-48e5-bf1f-f53c7b03a7f1

Male, 44.8 years: Mucoepidermoid carcinoma (ICD-O-3 8430/3) of the major salivary gland; specimen biopsied or resected from the brain. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
